Gene-level copy-number profile of tumor specimen TCGA-62-A46U-01A from TCGA case TCGA-62-A46U, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 71.2 years (25,998 days).
Specimen TCGA-62-A46U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.7dd37ab8-d86b-44ff-a411-98b2fd79394a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-62-A46U-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1bab334d-8079-4a69-8e87-a22d90d11092

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 106; copy number 2: 8,527; copy number 3: 13,964; copy number 4: 29,927; copy number 5: 3,968; copy number 6: 1,733; copy number 7: 509; copy number 8: 513; copy number 9: 256; copy number 10: 11; copy number 11: 305.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-62-A46U-01A-11D-A24C-01): tumor purity 0.25, ploidy 3.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 572 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,890,595–160,262,549, 305 genes, copy number 11 (within-gene range 4–11) (broad region; genes not listed).
- chr6:37,543,553–48,214,794, 245 genes, copy number 9 (broad region; genes not listed).
- chr6:49,714,325–49,820,503, 1 gene, copy number 10 (within-gene range 5–10): AL121974.1.
- chr6:49,785,660–50,415,875, 10 genes, copy number 10: PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL132799.1.
- chr17:52,390,515–54,365,634, 11 genes, copy number 9 (within-gene range 6–9): LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B.

Autosomal genes at a single copy (total copy number 1): 106. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
